Somatic mutation profile of tumor specimen TARGET-10-PARTPW-09A (aliquot TARGET-10-PARTPW-09A-01D) from TARGET case TARGET-10-PARTPW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,483 days).
Specimen TARGET-10-PARTPW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 056c0f25-65e7-49a6-9a52-4123c9ba61ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTPW-10A (Blood Derived Normal), aliquot TARGET-10-PARTPW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d33d4040-c6eb-40bf-8f09-404193c75f9c

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, 3'UTR 3, Silent 2, 5'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, Splice Region 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD5 | c.3579T>A p.F1193L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1021870588, COSV58973543, COSV58976914; called by muse, mutect2, varscan2
- COPS7A | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57526984; called by muse, mutect2, varscan2
- GDF9 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV51526856; called by muse, mutect2, varscan2
- GPR20 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs1361384111, COSV66684727; called by muse, mutect2, varscan2
- HSP90AA1 | c.1338+1G>T p.X446_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as COSV104369604, COSV53490209; called by muse, mutect2, varscan2
- MYOZ3 | c.587+5G>A | Splice Region (SNP) | VAF 20/37 reads (54%) | catalogued as COSV51740492; called by muse, mutect2, varscan2
- NOTCH1 | c.4818_4820delinsGGGGGTCGGAAGGTC p.F1606_K1607delinsLGVGRS | In Frame Ins (INS) | VAF 18/39 reads (46%) | catalogued as COSV53046198, COSV53073751; called by pindel, varscan2*
- PTCHD4 | c.2231G>C p.R744P | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV59791540, COSV59795118; called by muse, mutect2, varscan2
- RPL5 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59873502; called by mutect2, varscan2
- SMYD1 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.79); PolyPhen benign (0.273); catalogued as COSV70225610; called by muse, mutect2, varscan2
- VWDE | c.2309C>T p.T770M | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs780962187, COSV51722439; called by muse, mutect2, varscan2
- KCNH3 | c.3000_3001insACCCCCTTTA p.E1001Tfs*14 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- UBTF | c.607dup p.Q203Pfs*46 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- RNPEPL1 | c.2088A>T p.A696= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- RPS15A | c.204G>A p.R68= | Silent (SNP) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- FBXL20 | c.*6867_*6868insCGAGTCCA | 3'UTR (INS) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- GABRG3 | c.1123-1788C>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- GCN1 | c.3631-68C>T | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- GRK2 | c.*979dup | 3'UTR (INS) | VAF 14/32 reads (44%) | catalogued as rs781487718; called by mutect2, varscan2
- PCDHB15 | c.*26G>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs782810320, COSV50970790; called by muse, mutect2, varscan2
- SAMD12 | c.-63C>T | 5'UTR (SNP) | VAF 38/132 reads (29%) | called by muse, mutect2, varscan2
- SCAND1 | c.-132G>T | 5'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- TMEM63A | c.676-148G>A | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- TUBB4A | c.58-139_58-138insTTTACG | Intron (INS) | VAF 5/19 reads (26%) | called by mutect2, varscan2
